Gene-level copy-number profile of tumor specimen TARGET-40-0A4I8U-01A from TARGET case TARGET-40-0A4I8U, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.1 years (7,328 days).
Specimen TARGET-40-0A4I8U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.720bd506-a67c-53f0-8268-309c231f8b62.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I8U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 413 have no estimate.
https://portal.gdc.cancer.gov/files/01a2f1d0-1368-434f-905b-9735d282efb1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,425; copy number 1: 2,078; copy number 2: 21,804; copy number 3: 20,554; copy number 4: 7,272; copy number 5: 3,640; copy number 6: 2,060; copy number 7: 275; copy number 8: 219; copy number 9: 163; copy number 10: 222; copy number 11: 74; copy number 12: 21; copy number 14: 152; copy number 15: 37; copy number 16: 45; copy number 18: 28; copy number 19: 84; copy number 20: 34; copy number 24: 2; copy number 27: 21.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,709,235–116,723,581, 2 genes: TUSC7, AC108713.1.
- chr7:147,080,934–147,167,572, 3 genes: CNTNAP2-AS1, DUTP3, RANP2.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.
- chr11:84,545,131–84,997,768, 7 genes: HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1.
- chr19:43,211,791–43,269,530, 2 genes (within-gene range 0–2): CEACAMP10, PSG9.
- chr22:28,992,721–29,268,209, 10 genes: ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P, EMID1, RHBDD3, AL031186.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,077 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,745,382–24,970,865, 6 genes, copy number 6: CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1.
- chr1:46,432,129–72,282,539, 480 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:72,274,552–116,769,229, 763 genes, copy number 5 (within-gene range 5–8) (broad region; genes not listed).
- chr1:143,541,768–161,089,558, 790 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:161,505,430–162,979,793, 45 genes, copy number 5: FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1, RPL31P11, Y_RNA, FCRLA, FCRLB, RN7SL466P, DUSP12, AL359541.1, ATF6, AL391825.1, OLFML2B, AL590408.1, NOS1AP, AL450163.1, MIR4654, AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1.
- chr2:13,537,673–24,201,698, 144 genes, copy number 5–7 (broad region; genes not listed).
- chr2:24,210,650–24,222,201, 1 gene, copy number 7: AC009228.1.
- chr2:39,786,453–67,311,439, 428 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr2:67,796,054–71,686,768, 100 genes, copy number 5–7 (broad region; genes not listed).
- chr2:81,967,079–92,035,000, 268 genes, copy number 9–27 (broad region; genes not listed).
- chr4:49,203,171–55,905,086, 100 genes, copy number 5 (broad region; genes not listed).
- chr4:127,094,410–154,491,799, 363 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr6:42,564,029–46,080,348, 102 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr6:46,220,736–47,042,350, 14 genes, copy number 6 (within-gene range 4–6): RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:47,878,028–48,214,794, 4 genes, copy number 5: PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr6:49,077,712–51,623,428, 37 genes, copy number 5: AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1.
- chr7:6,879,627–6,939,603, 5 genes, copy number 6: OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP.
- chr7:62,275,361–79,453,667, 412 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr7:78,347,142–84,984,506, 55 genes, copy number 5–7 (within-gene range 1–7): RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8.
- chr7:94,278,680–94,395,608, 2 genes, copy number 6: AC002074.1, AC002074.2.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr12:26,800,843–37,576,384, 165 genes, copy number 5–8 (broad region; genes not listed).
- chr14:36,070,427–40,390,547, 64 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr14:51,344,914–51,825,422, 16 genes, copy number 5 (within-gene range 4–5): AL358332.1, LINC02310, SETP2, FRMD6-AS2, FRMD6, RNU6-1291P, AL122125.1, FRMD6-AS1, RNA5SP385, RNU6-301P, AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3.
- chr14:59,595,976–59,870,776, 2 genes, copy number 5 (within-gene range 2–5): RTN1, MIR5586.
- chr17:7,705,202–20,681,799, 485 genes, copy number 5–24 (within-gene range 3–24) (broad region; genes not listed).
- chr17:22,090,743–27,003,259, 31 genes, copy number 5–18: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2, AC069061.1, AC069061.2, PDLIM1P3.
- chr17:62,231,470–66,198,238, 134 genes, copy number 5 (broad region; genes not listed).
- chr18:10,124,588–10,372,387, 3 genes, copy number 5 (within-gene range 4–5): AP005271.1, AP005209.2, AP005209.1.
- chr18:12,785,478–13,185,617, 9 genes, copy number 5 (within-gene range 4–5): PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2.
- chr18:58,659,858–59,085,920, 14 genes, copy number 5: AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8, ZNF532, RNU2-69P, OACYLP, AC040963.1.
- chr19:27,638,483–28,125,430, 15 genes, copy number 11: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:29,083,094–30,085,893, 28 genes, copy number 19: AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:31,348,881–31,417,794, 1 gene, copy number 9 (within-gene range 4–9): AC025809.1.
- chr19:31,421,997–32,072,113, 8 genes, copy number 9 (within-gene range 2–9): AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837.
- chr21:24,306,939–24,547,942, 1 gene, copy number 20 (within-gene range 2–20): LINC01684.
- chr21:31,060,600–31,063,168, 1 gene, copy number 11: UBE3AP2.
- chr21:43,865,223–46,665,124, 129 genes, copy number 10–15 (within-gene range 2–15) (broad region; genes not listed).
- chr22:21,103,016–25,197,448, 290 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr22:31,388,733–32,037,995, 24 genes, copy number 5 (within-gene range 2–5): RNU6-338P, DRG1, EIF4ENIF1, AL096701.3, RNU6-28P, SFI1, AL096701.4, H2AZP6, AL096701.2, AL096701.1, PISD, MIR7109, PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P.

Autosomal genes at a single copy (total copy number 1): 1,219. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
